Somatic mutation profile of tumor specimen TCGA-VD-A8K7-01B (aliquot TCGA-VD-A8K7-01B-11D-A39W-08) from TCGA case TCGA-VD-A8K7, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 39.1 years (14,294 days).
Specimen TCGA-VD-A8K7-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc36dd2e-0348-4182-93c0-cbd4747eb9c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-A8K7-10A (Blood Derived Normal), aliquot TCGA-VD-A8K7-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4b8c0cd-0d50-42eb-b3cd-e4741320e9ca

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 30/75 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CCDC126 | c.92A>G p.H31R | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1324302686; called by muse, mutect2, varscan2
- CCDC126 | c.93C>T p.H31= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as rs866686971; called by muse, mutect2, varscan2
